Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7IS, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7IS-01A (Primary Tumor).

Neuropathology

Commentary:

This case was initially diagnosed anaplastic astrocytoma WHO grade III.
Upon review, transition to Glioblastoma appears likely.

Diagnosis:

Anaplastic astrocytoma WHO grade III

ICD-O-3

Astrocytoma, grade III 9401/3

Site: brain, supratentorial, NOS
C71.0

hw 9/30/13

Untranslated original report
is housed at the BCR.

Criteria	hw 11/15/13	Yes	No

Source: NCI Genomic Data Commons file 7a15c5cf-d04c-4ffe-a6ab-01e78bb5bc35 (TCGA-S9-A7IS.B8C99516-595F-4A10-B400-BEA806E9A6FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).